Gene-level copy-number profile of tumor specimen ALCH-B400-TTP1-A from ALCHEMIST case ALCH-B400, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.8 years (26,219 days).
Specimen ALCH-B400-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9e4cc141-d14c-43b3-89d8-3d36f58afb0d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B400-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,249 have no estimate.
https://portal.gdc.cancer.gov/files/d07920f7-70b2-4d04-91f9-f63fa185360c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 82; copy number 1: 264; copy number 2: 57,126; copy number 3: 607; copy number 4: 188; copy number 5: 34; copy number 6: 19; copy number 7: 14; copy number 8: 5; copy number 9: 2; copy number 10: 2; copy number 11: 6; copy number 12: 2; copy number 13: 1; copy number 14: 5; copy number 15: 1; copy number 16: 1; copy number 17: 3; copy number 18: 2; copy number 20: 1; copy number 24: 1; copy number 25: 2; copy number 30: 1; copy number 31: 3; copy number 86: 1; copy number 153: 1.

Homozygous deletions (total copy number 0; autosomes only): 82 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,232,237–1,235,041, 1 gene: B3GALT6.
- chr1:1,253,909–1,273,864, 1 gene: UBE2J2.
- chr1:1,311,585–1,324,687, 3 genes (within-gene range 0–14): INTS11, MIR6727, AL139287.1.
- chr1:1,426,128–1,427,787, 1 gene: TMEM88B.
- chr2:202,265,736–202,336,727, 8 genes: NOP58, SNORD70, SNORD70B, SNORD11B, SNORD11, AC064836.3, RN7SL753P, PIMREGP1.
- chr3:47,931,808–47,931,914, 1 gene (within-gene range 0–2): Y_RNA.
- chr4:151,099,624–151,104,642, 2 genes (within-gene range 0–1): RPS3A, SNORD73B.
- chr4:151,103,827–151,103,891, 1 gene (within-gene range 0–1): SNORD73A.
- chr6:110,982,015–111,028,263, 1 gene: RPF2.
- chr7:74,174,231–74,229,834, 3 genes: EIF4H, MIR590, LAT2.
- chr8:30,678,066–30,767,006, 3 genes: GSR, UBXN8, HIKESHIP3.
- chr8:142,111,414–142,185,527, 2 genes: AC103758.1, MIR4472-1.
- chr8:142,763,116–142,778,224, 4 genes: AC083841.1, LYNX1-SLURP2, SLURP2, LYNX1.
- chr9:42,183,659–42,499,134, 10 genes: SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6.
- chr9:42,579,414–42,714,539, 5 genes: BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1.
- chr9:125,241,663–125,257,071, 1 gene: AL354710.2.
- chr10:68,414,064–68,472,121, 3 genes (within-gene range 0–1): DNA2, RPL26P29, RNA5SP319.
- chr11:1,662,584–1,667,856, 2 genes: AP006285.1, FAM99A.
- chr12:32,339,368–32,354,144, 2 genes (within-gene range 0–2): AC026356.1, AC026356.2.
- chr12:123,458,088–123,473,154, 1 gene (within-gene range 0–1): SNRNP35.
- chr12:123,536,409–123,585,115, 2 genes (within-gene range 0–2): MIR3908, TMED2-DT.
- chr12:132,200,436–132,201,287, 1 gene (within-gene range 0–5): AC138466.4.
- chr13:113,815,630–113,864,076, 2 genes (within-gene range 0–2): GAS6-AS1, GAS6.
- chr16:788,046–800,737, 2 genes (within-gene range 0–11): CHTF18, GNG13.
- chr16:1,078,781–1,080,142, 1 gene: SSTR5.
- chr17:39,210,541–39,225,945, 1 gene: STAC2.
- chr17:81,339,183–81,345,966, 1 gene: AC027601.5.
- chr17:82,978,525–82,981,738, 1 gene (within-gene range 0–2): AC130371.1.
- chr19:453,134–474,983, 2 genes (within-gene range 0–7): RNA5SP462, ODF3L2.
- chr19:507,497–519,654, 1 gene (within-gene range 0–4): TPGS1.
- chr19:1,307,401–1,307,719, 1 gene (within-gene range 0–2): RPS15P9.
- chr19:32,597,006–32,678,300, 6 genes (within-gene range 0–2): ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP.
- chr20:62,648,961–62,650,767, 1 gene (within-gene range 0–4): AL357033.4.
- chr21:36,295,173–36,295,702, 1 gene: SRSF9P1.
- chr21:44,328,944–44,335,851, 2 genes (within-gene range 0–2): AP001062.3, AP001062.1.
- chr21:45,914,296–45,919,483, 1 gene (within-gene range 0–3): AJ239328.1.
- chr22:17,192,936–17,193,308, 1 gene (within-gene range 0–1): AC005300.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 105 genes in 51 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,059,708–1,069,355, 2 genes, copy number 7: AL390719.1, AL645608.8.
- chr1:1,167,104–1,232,067, 9 genes, copy number 5–6: MIR200B, MIR200A, MIR429, AL390719.2, TTLL10-AS1, TTLL10, TNFRSF18, TNFRSF4, SDF4.
- chr1:1,242,446–1,251,334, 2 genes, copy number 6–31: C1QTNF12, AL162741.1.
- chr1:1,292,390–1,311,677, 3 genes, copy number 14 (within-gene range 0–287): ACAP3, MIR6726, PUSL1.
- chr1:1,335,276–1,349,418, 1 gene, copy number 5 (within-gene range 1–5): DVL1.
- chr1:1,430,539–1,434,573, 1 gene, copy number 20: LINC01770.
- chr1:2,632,568–2,636,620, 1 gene, copy number 7 (within-gene range 3–7): MMEL1-AS1.
- chr1:3,021,467–3,022,903, 1 gene, copy number 7: ACTRT2.
- chr1:3,454,665–3,481,113, 1 gene, copy number 5: ARHGEF16.
- chr5:659,862–693,352, 2 genes, copy number 8 (within-gene range 3–10): TPPP, AC026740.1.
- chr7:1,232,872–1,269,267, 2 genes, copy number 5–15: UNCX, AC073094.1.
- chr8:142,212,080–142,545,009, 4 genes, copy number 5–6: TSNARE1, RN7SL260P, AC134682.1, ADGRB1.
- chr8:142,784,882–142,812,120, 3 genes, copy number 11: LY6D, AC083841.2, AC083841.4.
- chr8:143,573,490–143,603,224, 3 genes, copy number 31–153 (within-gene range 14–153): AC067930.4, NAPRT, TIGD5.
- chr8:143,758,153–143,840,256, 5 genes, copy number 5–18: AC105219.3, PUF60, AC234917.3, AC234917.1, AC234917.2.
- chr9:42,566,679–42,569,353, 2 genes, copy number 7: BX088651.4, BX088651.1.
- chr11:1,049,880–1,055,749, 1 gene, copy number 7: LINC02688.
- chr12:132,196,372–132,329,589, 1 gene, copy number 5 (within-gene range 0–14): GALNT9.
- chr12:132,282,814–132,363,348, 6 genes, copy number 5 (within-gene range 5–14): AC148477.4, AC148477.1, AC148477.7, AC148477.8, AC148477.6, AC148477.9.
- chr12:132,457,160–132,460,024, 1 gene, copy number 6: AC079031.1.
- chr13:113,883,667–113,923,512, 2 genes, copy number 5–6: BX072579.2, LINC00452.
- chr14:104,681,146–104,722,535, 2 genes, copy number 6 (within-gene range 6–13): INF2, AL583722.3.
- chr14:104,800,596–104,804,712, 1 gene, copy number 7: ZBTB42.
- chr14:104,821,201–104,836,852, 3 genes, copy number 5: LINC00638, RPS26P49, RPS2P4.
- chr14:104,857,792–104,905,204, 3 genes, copy number 5–7: AL583810.1, CEP170B, AL583810.3.
- chr14:105,472,962–105,499,575, 4 genes, copy number 11–17: CRIP2, CRIP1, AL928654.3, TEDC1.
- chr14:105,536,861–105,537,239, 1 gene, copy number 6: ATP5MC1P1.
- chr14:105,583,731–105,588,395, 1 gene, copy number 9: IGHA2.
- chr14:105,620,506–105,669,843, 4 genes, copy number 8–25 (within-gene range 2–25): IGHG4, MIR8071-1, COPDA1, IGHGP.
- chr16:784,974–788,397, 1 gene, copy number 11 (within-gene range 0–11): RPUSD1.
- chr16:848,525–849,065, 1 gene, copy number 12: AL031008.1.
- chr16:975,761–1,000,926, 3 genes, copy number 7–10 (within-gene range 4–10): CEROX1, SOX8, AC009041.1.
- chr16:89,046,172–89,052,966, 1 gene, copy number 5: AC135782.1.
- chr16:89,159,146–89,169,147, 2 genes, copy number 7–8: LINC00304, LINC02138.
- chr16:89,906,157–89,918,233, 1 gene, copy number 6 (within-gene range 1–6): AC092143.3.
- chr17:81,303,771–81,330,674, 2 genes, copy number 5–11: LINC00482, TMEM105.
- chr19:397,589–460,996, 3 genes, copy number 5–86 (within-gene range 0–86): AC010641.1, C2CD4C, SHC2.
- chr20:62,513,909–62,551,526, 2 genes, copy number 14 (within-gene range 3–14): AL499627.1, MIR1-1HG-AS1.
- chr20:63,293,186–63,337,449, 2 genes, copy number 5: COL20A1, RNU6-994P.
- chr21:44,414,588–44,462,196, 4 genes, copy number 5–6 (within-gene range 5–10): TRPM2-AS, AP001065.2, LRRC3-DT, LRRC3.

Autosomal genes at a single copy (total copy number 1): 256. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
